Gene-level copy-number profile of tumor specimen AP-B2SL-EL from APOLLO case AP-B2SL, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2.
Specimen AP-B2SL-EL: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bea80cf9-c233-4e85-9f1f-f4301741ddd0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-B2SL-MF (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/ea982ab1-e242-480a-9b8b-29d0e72c368b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 432; copy number 1: 17,257; copy number 2: 35,410; copy number 3: 4,334; copy number 4: 977; copy number 5: 286; copy number 6: 210.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:86,087,526–86,087,847, 1 gene: PTP4A1P4.
- chr9:40,767,870–40,929,092, 3 genes: AL353626.1, AL353626.2, MIR1299.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 496 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:61,057,158–84,921,844, 338 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:125,648,327–126,008,930, 1 gene, copy number 5 (within-gene range 4–5): AC016074.2.
- chr8:125,859,721–137,698,467, 134 genes, copy number 5–6 (broad region; genes not listed).
- chr8:140,657,900–141,518,737, 23 genes, copy number 5: PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1.

Autosomal genes at a single copy (total copy number 1): 14,829. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
